Surgical pathology report (de-identified scan), TCGA case TCGA-B1-A654, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-A654-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

KIDNEY, RIGHT, PARTIAL NEPHRECTOMY -

- PAPILLARY RENAL CELL CARCINOMA, TYPE 1, SOLID VARIANT (SEE COMMENT).
- CARCINOMA MEASURES 4.0 cm IN GREATEST DIMENSION.
- CARCINOMA IS CONFINED TO THE KIDNEY.
- FUHRMAN NUCLEAR GRADE IS 1-2 OF 4.
- ALL SURGICAL MARGINS OF RESECTION ARE NEGATIVE FOR CARCINOMA.
- LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- BACKGROUND RENAL PARENCHYMA WITH CHANGES ASSOCIATED WITH PROXIMITY TO TUMOR.
- TNM PATHOLOGIC STAGE (AJCC 7th EDITION): PT1A NX MX.

COMMENT:

Immunohistochemical profile of the neoplasm is as follows:

WT1	negative
CD56	focal positive
CD57	focal positive
P504S(racemase)	positive
CK7	positive
RCC	positive

Although metanephric adenoma was considered in the morphologic differential diagnosis, CK7 and racemase positivity and WT1 negativity confirm the diagnosis of papillary renal cell carcinoma.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:

LATERALITY:

TUMOR SITE:

FOCALITY:

TUMOR SIZE:

MACROSCOPIC EXTENT OF TUMOR:

HISTOLOGIC TYPE:

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

PATHOLOGIC STAGING (pTNM):

Partial nephrectomy

Right

Middle

Unifocal

Greatest dimension: 4.0 cm

Additional dimensions: 3.0X2.5 cm

Tumor limited to kidney

Papillary renal cell carcinoma

G1

pT1a

pNX

Number of regional lymph nodes examined: 0

pMX

Margins uninvolved by invasive carcinoma

Not present

MARGINS:

ADRENAL GLAND:

LYMPH-VASCULAR INVASION (LVI): Absent/not identified

KIDNEY-RESIDUAL TUMOR (R): RX

ICD-O-3

Carcinoma, papillary renal cell 8266/3

Site R Kidney NOS 064.9

JW 5/16/13

Criteria	W 3/29/13	Yes	No
HIFAA Discrepancy			

Source: NCI Genomic Data Commons file 76d036de-560d-4db6-8e6c-f25e1fc1b667 (TCGA-B1-A654.2D6AEFBE-209A-49B4-9EF5-2E6F6C2ED51F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).